Somatic mutation profile of tumor specimen ALCH-AE14-TTP1-A (aliquot ALCH-AE14-TTP1-A-1-0-D-A604-36) from ALCHEMIST case ALCH-AE14, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 52.4 years (19,146 days).
Specimen ALCH-AE14-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7377afe7-1e72-40de-9f97-a7c73adec4d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE14-NB1-A (Blood Derived Normal), aliquot ALCH-AE14-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/347a0b00-0c38-42c3-a998-171cfd50a59b

The open-access MAF lists 102 somatic variants for this specimen: 75 protein-altering or splice-affecting, 19 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 19, Nonsense Mutation 4, Intron 3, RNA 3, Frame Shift Del 2, In Frame Del 1, Splice Region 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 35/238 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP23 | c.3175G>A p.V1059I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1234458584; called by muse, mutect2
- COL14A1 | c.2839G>A p.A947T | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1225333535; called by muse, mutect2
- CRNN | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV55120885, COSV99664307; called by muse, mutect2
- CSMD3 | c.161C>A p.T54K | Missense Mutation (SNP) | VAF 58/586 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.026); catalogued as COSV52113522; called by muse, mutect2
- CTH | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 111/1043 reads (11%) | catalogued as COSV61007606; called by muse, mutect2, varscan2
- DAGLB | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs781562515; called by muse, mutect2, varscan2
- DDX19A | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as rs1040625855, COSV100156171; called by muse, mutect2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs754135731; called by muse*, mutect2, varscan2*
- EPHA6 | c.2585G>T p.G862V (on ENST00000389672 / NM_001080448.3; = p.G254V on NM_173655.4) | Missense Mutation (SNP) | VAF 31/405 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67566754; called by muse, mutect2
- FAT2 | c.4601T>C p.I1534T | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1034213539; called by muse, mutect2
- FAT3 | c.7823G>T p.S2608I | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs946213410; called by muse, mutect2
- HECW1 | c.4012C>A p.L1338I | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.882); catalogued as COSV101223840; called by muse, mutect2, varscan2
- KCNH7 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 42/628 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59790106; called by muse, mutect2
- LRP1B | c.4182G>T p.W1394C | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101252966; called by muse, mutect2, varscan2
- MED16 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as rs766942790; called by muse, mutect2, varscan2
- MGAM | c.2009G>A p.C670Y | Missense Mutation (SNP) | VAF 50/546 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1444380400; called by muse, mutect2
- MKI67 | c.9511G>T p.E3171* | Nonsense Mutation (SNP) | VAF 15/228 reads (7%) | catalogued as COSV64073460; called by muse, mutect2
- MTTP | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 58/572 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.769); catalogued as COSV55506899; called by muse, mutect2, varscan2
- NLRP13 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61620786; called by muse, mutect2
- POLQ | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 50/478 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs761630032, COSV51761801; called by muse, mutect2, varscan2
- SCEL | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 25/618 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV62993879; called by muse, mutect2
- SOCS5 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 37/459 reads (8%) | catalogued as COSV60605808; called by muse, mutect2
- STAC | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99829543; called by muse, mutect2
- TBX20 | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV101282373; called by muse, mutect2, varscan2
- TPO | c.1508G>A p.R503K | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1379407306; called by muse, mutect2
- ZDBF2 | c.6785C>G p.A2262G | Missense Mutation (SNP) | VAF 21/357 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV65626663; called by muse, mutect2
- ADAMTS6 | c.2986C>A p.P996T | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2
- AIM2 | c.769del p.T257Lfs*8 | Frame Shift Del (DEL) | VAF 33/317 reads (10%) | called by mutect2, pindel, varscan2
- AP2A2 | c.2327C>G p.P776R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ARAP2 | c.4850A>T p.E1617V | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARMCX3 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- C17orf78 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CALCRL | c.187G>C p.V63L | Missense Mutation (SNP) | VAF 54/529 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMTA1 | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CORO1B | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CPSF1 | c.3070T>A p.Y1024N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, varscan2
- CRNN | c.569A>T p.E190V | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2
- DNAH11 | c.3136G>T p.A1046S | Missense Mutation (SNP) | VAF 57/448 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM199X | c.1044G>T p.R348S | Missense Mutation (SNP) | VAF 43/506 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); called by muse, mutect2
- FANCD2 | c.2308A>G p.K770E | Missense Mutation (SNP) | VAF 35/672 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- GSTM5 | c.177T>A p.N59K | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- IGDCC4 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- INO80D | c.507G>T p.K169N | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KIF4B | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 52/769 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.292); called by muse, mutect2
- KRTAP4-5 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- LIN54 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 40/804 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2
- MARK1 | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 82/576 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEFV | c.1610+5A>T | Splice Region (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- METTL8 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.619); called by muse, mutect2
- MID1 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MPDZ | c.4463A>T p.K1488M | Missense Mutation (SNP) | VAF 47/595 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- NFKBIB | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.208); called by muse, mutect2
- NLRP13 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- OR4C5 | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 51/596 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- OR8K5 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 62/590 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- PAXIP1 | c.1701G>T p.Q567H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PCDH11X | c.2706A>T p.R902S | Missense Mutation (SNP) | VAF 39/1028 reads (4%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- PKD1L1 | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 48/544 reads (9%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.094); called by muse, mutect2
- POTEJ | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 44/1028 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- RYR2 | c.10772T>A p.L3591Q | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC8A1 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SLITRK6 | c.2488G>T p.E830* | Nonsense Mutation (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- SMG1 | c.3475C>G p.P1159A | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TCF4 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 133/1245 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- TRDN | c.488C>A p.T163K | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.099); called by muse, mutect2
- TRO | c.4032C>A p.S1344R | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- UNC5C | c.1519C>A p.Q507K | Missense Mutation (SNP) | VAF 36/516 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, mutect2
- USP24 | c.3006_3009del p.Q1002Hfs*8 | Frame Shift Del (DEL) | VAF 85/608 reads (14%) | called by mutect2, pindel, varscan2
- VCAN | c.3299A>T p.H1100L | Missense Mutation (SNP) | VAF 28/574 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- VSIG4 | c.159G>T p.L53F | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.323); called by muse, mutect2
- WDR64 | c.2660T>A p.I887N | Missense Mutation (SNP) | VAF 21/303 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2
- WDR75 | c.2459G>T p.R820M | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- ZNF711 | c.1413G>T p.K471N | Missense Mutation (SNP) | VAF 85/1101 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2
- ZNF99 | c.1442A>G p.Y481C | Missense Mutation (SNP) | VAF 57/594 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- ARMCX2 | c.177C>A p.A59= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as rs781894857, COSV57530747; called by muse, mutect2
- C17orf78 | c.522C>T p.N174= | Silent (SNP) | VAF 40/339 reads (12%) | called by muse, mutect2, varscan2
- EGFLAM | c.2523C>A p.I841= (on ENST00000354891 / NM_001205301.2; = p.I833= on NM_152403.4) | Silent (SNP) | VAF 26/445 reads (6%) | called by muse, mutect2
- FAM114A1 | c.360C>T p.S120= | Silent (SNP) | VAF 13/123 reads (11%) | called by muse, varscan2
- FAM171B | c.2064C>A p.S688= | Silent (SNP) | VAF 46/506 reads (9%) | catalogued as COSV59001310; called by muse, mutect2
- GNG4 | c.129C>A p.A43= | Silent (SNP) | VAF 12/114 reads (11%) | called by muse, varscan2
- HCRTR2 | c.585C>A p.T195= | Silent (SNP) | VAF 57/614 reads (9%) | catalogued as COSV63796120, COSV63799662; called by muse, mutect2
- HTR4 | c.402C>T p.T134= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV100087597; called by muse, mutect2
- LRP1B | c.11472T>A p.S3824= | Silent (SNP) | VAF 80/808 reads (10%) | called by muse, mutect2
- NMUR2 | c.177G>A p.G59= | Silent (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2, varscan2
- OR2M4 | c.246C>A p.I82= | Silent (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- OR2W3 | c.243G>C p.L81= | Silent (SNP) | VAF 21/176 reads (12%) | called by muse, mutect2, varscan2
- OR4A15 | c.507C>A p.P169= | Silent (SNP) | VAF 40/464 reads (9%) | called by muse, mutect2
- OR4K15 | c.234C>A p.R78= (on ENST00000305051; = p.R54= on NM_001005486.1) | Silent (SNP) | VAF 16/448 reads (4%) | called by muse, mutect2
- OR4M1 | c.705C>A p.T235= | Silent (SNP) | VAF 22/317 reads (7%) | catalogued as COSV60059723; called by muse, mutect2
- ST3GAL4 | c.177T>C p.F59= (on ENST00000392669 / NM_001254758.1; = p.F55= on NM_006278.3) | Silent (SNP) | VAF 14/146 reads (10%) | called by muse, varscan2
- UMODL1 | c.3498G>C p.R1166= (on ENST00000408910 / NM_001004416.2; = p.R1294= on NM_173568.3) | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV68571300; called by muse, mutect2, varscan2
- ZBTB12 | c.1149T>A p.G383= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- ZNF71 | c.264G>C p.L88= | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-2187G>T | Intron (SNP) | VAF 22/508 reads (4%) | catalogued as COSV99424799; called by muse, mutect2
- AKAP13 | c.4800-2172G>T | Intron (SNP) | VAF 16/341 reads (5%) | called by muse, mutect2
- ARHGEF9 | c.-43G>T | 5'UTR (SNP) | VAF 34/462 reads (7%) | called by muse, mutect2
- FMR1 | c.*297G>T | 3'UTR (SNP) | VAF 30/388 reads (8%) | called by muse, mutect2
- LINC02448 | n.429C>G | RNA (SNP) | VAF 26/480 reads (5%) | called by muse, mutect2
- MEIS3P1 | n.941A>T | RNA (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- PEX26 | c.230+52G>C | Intron (SNP) | VAF 10/268 reads (4%) | called by muse, mutect2
- RNF217-AS1 | n.3313T>C | RNA (SNP) | VAF 38/436 reads (9%) | called by muse, mutect2
